Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A13M, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A13M-01A (Primary Tumor).

[page 1 of 4]
Clinical Diagnosis & History:

year old female with left thyroid mass, FNA consistent with atypical cells.

Specimens Submitted:

- 1: SP: Thyroid, Total thyroidectomy
2: SP: Delphine node

DIAGNOSIS:

1. SP: Thyroid, Total thyroidectomy:

Tumor Type: Papillary carcinoma, follicular variant

Histologic Grade: Well differentiated

Mitotic Activity: Not identified

Tumor Necrosis: Not identified

Tumor Location: Left lobe

Tumor Size: Greatest diameter is 2.0 cm.

Tumor Encapsulation: Completely surrounded

Capsular Invasion: Focal invasion
Single focus of capsular invasion

Blood Vessel Invasion: Not identified

Extrathyroid Extension: Not identified

Surgical Margins: Free of tumor

Tumor Multicentricity: Separate focus of papillary microcarcinoma, encapsulated, non-invasive in right lobe (0.7 cm)

Non-Neoplastic Thyroid:

ICD - 0 - 3

Carcinoma, papillary w follicular variant

8340/3

Site: thyroid, nos C73.9

hw
11/16/10

[page 2 of 4]
Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

INPATIENT

Clinical Diagnosis & History:

year old female with left thyroid mass, FNA consistent with atypical cells.

Specimens Submitted:

1: SP: Thyroid, Total thyroidectomy

2: SP: Delphine node

DIAGNOSIS:

1. SP: Thyroid, Total thyroidectomy:

Tumor Type:
Papillary carcinoma, follicular variant

Histologic Grade:
Well differentiated

Mitotic Activity:
Not identified

Tumor Necrosis:
Not identified

Tumor Location:
Left lobe

Tumor Size:
Greatest diameter is 2.0 cm.

Tumor Encapsulation:
Completely surrounded

Capsular Invasion:
Focal invasion
Single focus of capsular invasion

Blood Vessel Invasion:
Not identified

Extrathyroid Extension:
Not identified

Surgical Margins:
Free of tumor

Tumor Multicentricity:
Separate focus of papillary microcarcinoma, encapsulated, non-invasive in right lobe (0.7 cm)

Non-Neoplastic Thyroid:

[page 3 of 4]
Exhibits nodular hyperplasia
Parathyroid Glands:
Not identified

- Four benign lymph nodes (0/4)

2. SP: Lymph node, Delphine; Excision:
-One benign lymph node (0/1)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh, labeled "Total thyroid" and consists of a thyroid weighing 24 g. The right lobe measures 5.5 x 2.0 x 2.0 cm, the left lobe measures 4.3 x 2.3 x 2.3 cm and the isthmus measures 2.0 x 2.0 x 1.0 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a 1.5 x 1.1 x 1.0 cm yellow tinged fluid filled cyst with a 1.2 cm papillary excrescence, identified in the right lobe. The cyst wall lining is white and trabecular. There are two 0.3 cm in greatest dimension white-tan firm nodules identified in the right lobe. Sectioning through the remaining tissue reveals a 2.0 x 2.0 x 1.4 cm encapsulated yellow-tan tumor in the left lobe abutting the anterior and posterior capsule. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen are submitted for TPS, and a photograph has been taken. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

C-- cyst
T--left lobe tumor
RN--right lobe nodules
RL - right lobe
LL - left lobe
I - isthmus

2). The specimen is received fresh, labeled "Delphine node" and consists of yellow-pink portion of soft tissue measuring 0.5 x 0.3 x 0.1 cm. The specimen is entirely submitted.

Summary of sections:
U--undesignated

Summary of Sections:

Part 1: SP: Thyroid, Total thyroidectomy

Block	Sect. Site	PCs
4	C	5
3	I	4
6	LL	8
7	RL	13
2	RN	4
4	T	6

Part 2: SP: Delphine node

Block	Sect. Site	PCs
-------	------------	-----

Source: NCI Genomic Data Commons file 3685e07e-22ce-4b8c-a425-60c162a67486 (TCGA-DJ-A13M.F7271934-A7FC-4BF5-A45A-5296AD308007.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).